Somatic mutation profile of tumor specimen TCGA-B8-5550-01A (aliquot TCGA-B8-5550-01A-01D-1534-10) from TCGA case TCGA-B8-5550, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 71.0 years (25,937 days).
Specimen TCGA-B8-5550-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33eacb47-8fb6-4fb6-bbbd-c3f7abbf0e24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-5550-10A (Blood Derived Normal), aliquot TCGA-B8-5550-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae5a0a93-2289-41be-adfa-dd270fecf83e

The open-access MAF lists 104 somatic variants for this specimen: 81 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 21, Frame Shift Del 13, Nonsense Mutation 5, Splice Site 4, Frame Shift Ins 3, 3'Flank 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDH | c.1714G>T p.D572Y | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV52708654; called by muse, mutect2, varscan2
- AKAP9 | c.981G>T p.K327N | Missense Mutation (SNP) | VAF 83/379 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62353071; called by muse, mutect2, varscan2
- AKAP9 | c.9784G>T p.D3262Y (on ENST00000359028; = p.D3238Y on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/399 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV62353080; called by muse, mutect2, varscan2
- ALK | c.1546+1G>A p.X516_splice | Splice Site (SNP) | VAF 78/233 reads (33%) | catalogued as COSV66562299, COSV99072907; called by muse, mutect2, varscan2
- ANTXR1 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774300710, COSV58013918; called by muse, mutect2, varscan2
- APPL2 | c.1615G>C p.V539L | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV51592277; called by muse, mutect2, varscan2
- ARHGAP26 | c.1698G>C p.K566N | Missense Mutation (SNP) | VAF 97/319 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV50836005; called by muse, mutect2, varscan2
- ARHGEF1 | c.274G>C p.A92P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV100529237; called by muse, mutect2, varscan2
- BCOR | c.2916C>A p.Y972* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV60703423, COSV60713533; called by muse, mutect2, varscan2
- BHLHE40 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV56576107; called by muse, mutect2
- CASK | c.1582+1G>A p.X528_splice | Splice Site (SNP) | VAF 31/346 reads (9%) | catalogued as COSV59371958; called by muse, mutect2
- CFAP61 | c.2396A>T p.Q799L | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV55639549; called by muse, mutect2, varscan2
- CMTM2 | c.604C>A p.H202N | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV51749288; called by muse, mutect2, varscan2
- CRB1 | c.2435A>T p.Q812L | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV66332123; called by muse, mutect2, varscan2
- CYFIP2 | c.1781T>C p.I594T (on ENST00000616178 / NM_001291722.2; = p.I569T on NM_014376.4) | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV59045802; called by muse, mutect2, varscan2
- DNAH5 | c.12588G>T p.Q4196H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54240900; called by muse, mutect2, varscan2
- DNAH8 | c.9251T>A p.L3084H | Missense Mutation (SNP) | VAF 115/631 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59466328; called by muse, mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as rs774662919; called by pindel, varscan2
- FAM91A1 | c.1245G>C p.E415D | Missense Mutation (SNP) | VAF 85/506 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58238398; called by muse, mutect2, varscan2
- FAT1 | c.8363A>C p.E2788A | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV71675242; called by muse, mutect2
- FBXL3 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV62919090; called by muse, mutect2, varscan2
- FLG | c.8663G>A p.G2888E | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.244); catalogued as rs755615149, COSV100912317, COSV99056715; called by mutect2, varscan2
- GAREM1 | c.889T>A p.F297I | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52513183; called by muse, mutect2, varscan2
- GIPC1 | c.917A>T p.E306V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV99466685; called by muse, mutect2, varscan2
- GNA13 | c.767T>A p.L256H | Missense Mutation (SNP) | VAF 52/248 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101457390, COSV71475049; called by muse, mutect2, varscan2
- GNG11 | c.36G>C p.K12N | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV50350459; called by muse, mutect2
- HCK | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52941173, COSV52945324; called by muse, mutect2, varscan2
- HEPACAM | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53431256; called by muse, mutect2, varscan2
- IQUB | c.853T>C p.C285R | Missense Mutation (SNP) | VAF 59/522 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV61241128; called by muse, mutect2, varscan2
- KIF1A | c.434G>T p.S145I | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57495843; called by muse, mutect2, varscan2
- KLHL9 | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs1390198442, COSV62922198; called by muse, varscan2
- LVRN | c.2276T>A p.I759K | Missense Mutation (SNP) | VAF 98/336 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63497859; called by muse, mutect2, varscan2
- MANSC1 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV67111265; called by muse, mutect2, varscan2
- MGARP | c.432G>T p.E144D | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as COSV67449679; called by muse, mutect2, varscan2
- MRGPRX3 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs762421702, COSV66934421; called by muse, mutect2, varscan2
- MSLN | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as COSV101242431; called by muse, mutect2
- NOTCH2 | c.2480-1G>T p.X827_splice | Splice Site (SNP) | VAF 42/209 reads (20%) | catalogued as COSV56698880; called by muse, mutect2, varscan2
- NOTCH3 | c.3591C>A p.Y1197* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV54642450; called by muse, mutect2
- OR8I2 | c.97T>G p.F33V | Missense Mutation (SNP) | VAF 76/618 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV56169303; called by muse, mutect2
- PCDH18 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61270509; called by muse, mutect2, varscan2
- PCDHB4 | c.1354C>A p.Q452K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.291); catalogued as COSV52024988, COSV99522431; called by muse, mutect2, varscan2
- PGBD2 | c.1571A>C p.Y524S | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61400694; called by muse, mutect2, varscan2
- PIKFYVE | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 104/673 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52245688; called by muse, mutect2, varscan2
- PLD3 | c.580A>T p.K194* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV62925382; called by muse, mutect2, varscan2
- POLR1B | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV54501286; called by muse, mutect2, varscan2
- POLR2A | c.1367T>G p.V456G | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100496358; called by muse, mutect2
- PRDM9 | c.1022A>G p.Y341C | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1203754097, COSV57003704, COSV99691363; called by muse, mutect2
- PRIM1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 80/396 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV57717838; called by muse, mutect2, varscan2
- PTPN9 | c.1657C>G p.Q553E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100144586; called by muse, mutect2
- RAB2A | c.83A>T p.D28V | Missense Mutation (SNP) | VAF 107/567 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52913044; called by muse, mutect2, varscan2
- ROS1 | c.728C>A p.T243K | Missense Mutation (SNP) | VAF 61/553 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV63858880; called by muse, mutect2, varscan2
- RSPH6A | c.888+1G>C p.X296_splice | Splice Site (SNP) | VAF 24/139 reads (17%) | catalogued as COSV99680145; called by muse, mutect2, varscan2
- SERINC4 | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV51050457; called by muse, mutect2, varscan2
- SKIDA1 | c.2678C>T p.S893F | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV71610689, COSV71611072; called by muse, mutect2, varscan2
- SLC2A3 | c.1156T>G p.W386G | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50005270; called by muse, mutect2
- SPAG17 | c.4226A>T p.E1409V | Missense Mutation (SNP) | VAF 117/518 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV60463869; called by muse, mutect2, varscan2
- SPINK5 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV56259042; called by muse, mutect2, varscan2
- SPP1 | c.470A>G p.D157G (on ENST00000395080 / NM_001040058.2; = p.D143G on NM_000582.2) | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV52952308; called by muse, mutect2, varscan2
- SUGCT | c.874G>C p.A292P | Missense Mutation (SNP) | VAF 163/1054 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.74); catalogued as COSV59343203; called by muse, mutect2, varscan2
- TTC7B | c.911A>C p.Y304S | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.986); catalogued as COSV60635542; called by muse, mutect2, varscan2
- USP35 | c.2185C>T p.Q729* | Nonsense Mutation (SNP) | VAF 12/113 reads (11%) | catalogued as COSV71573106; called by muse, mutect2, varscan2
- WFIKKN1 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV50194468; called by muse, mutect2, varscan2
- ZBTB5 | c.1312T>C p.C438R | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.962); catalogued as COSV100312984; called by muse, mutect2
- ZCCHC17 | c.620A>C p.D207A | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.29); catalogued as COSV104417526, COSV60003188; called by muse, mutect2, varscan2
- ZNF324B | c.1600A>C p.K534Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV100351824; called by muse, mutect2, varscan2
- AFTPH | c.1139_1163del p.V380Efs*23 | Frame Shift Del (DEL) | VAF 87/349 reads (25%) | called by mutect2, pindel, varscan2
- ANKH | c.639_642del p.Y213* | Frame Shift Del (DEL) | VAF 20/170 reads (12%) | called by mutect2, pindel
- BAP1 | c.1216dup p.E406Gfs*3 | Frame Shift Ins (INS) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- CDKN2AIP | c.714del p.K238Nfs*11 | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | called by mutect2, varscan2
- COL5A3 | c.4104_4105dup p.P1369Hfs*25 | Frame Shift Ins (INS) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- COX6B2 | c.36del p.K13Nfs*114 | Frame Shift Del (DEL) | VAF 21/124 reads (17%) | called by mutect2, pindel, varscan2
- CPEB4 | c.982del p.L328* | Frame Shift Del (DEL) | VAF 22/112 reads (20%) | called by mutect2, pindel
- EP300 | c.1256_1265del p.N419Ifs*9 | Frame Shift Del (DEL) | VAF 52/402 reads (13%) | called by mutect2, pindel, varscan2
- GLG1 | c.2062del p.I688* | Frame Shift Del (DEL) | VAF 50/306 reads (16%) | called by mutect2, pindel, varscan2
- HCRTR1 | c.546del p.M183Wfs*10 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- KIF13B | c.3572del p.P1191Qfs*10 | Frame Shift Del (DEL) | VAF 91/496 reads (18%) | called by mutect2, pindel, varscan2
- OR13G1 | c.808del p.V270Wfs*2 | Frame Shift Del (DEL) | VAF 35/215 reads (16%) | called by mutect2, pindel, varscan2
- PLXNB2 | c.580_582del p.R194del | In Frame Del (DEL) | VAF 7/57 reads (12%) | called by mutect2, pindel
- SPARC | c.397del p.E133Rfs*28 | Frame Shift Del (DEL) | VAF 51/184 reads (28%) | called by mutect2, pindel, varscan2
- TARS2 | c.1168_1172del p.Q390* | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- TEKT1 | c.125_128dup p.L44Efs*5 | Frame Shift Ins (INS) | VAF 38/234 reads (16%) | called by mutect2, pindel, varscan2
- AKNA | c.1467A>T p.G489= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV56314018; called by muse, mutect2, varscan2
- ALDH1A1 | c.264A>G p.L88= | Silent (SNP) | VAF 27/183 reads (15%) | catalogued as rs1417637685, COSV52793006; called by muse, mutect2, varscan2
- BRDT | c.1131G>A p.P377= | Silent (SNP) | VAF 66/304 reads (22%) | catalogued as rs774760560, COSV62866313; called by muse, mutect2, varscan2
- DSE | c.2235C>T p.N745= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs1268167457, COSV59066218; called by muse, mutect2, varscan2
- EPHB4 | c.2196C>G p.A732= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as rs762187229, COSV62269813, COSV62271105; called by muse, mutect2, varscan2
- EPS8L3 | c.918G>A p.K306= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV62610075; called by muse, mutect2, varscan2
- GABPB2 | c.822C>G p.T274= | Silent (SNP) | VAF 34/187 reads (18%) | catalogued as COSV64461215; called by muse, mutect2
- GPR179 | c.861A>C p.P287= (on ENST00000621958; = p.P286= on NM_001004334.4) | Silent (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2
- HNF1B | c.36C>A p.L12= | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- IFIT1 | c.771A>T p.A257= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs758085363, COSV65661631; called by muse, mutect2, varscan2
- IL17A | c.444C>A p.T148= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs201642273, COSV60685134; called by muse, mutect2, varscan2
- PZP | c.2325C>T p.A775= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs745393431, COSV54361326; called by muse, mutect2, varscan2
- SCN3B | c.225C>T p.Y75= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs763016117, COSV54798927; called by muse, mutect2, varscan2
- STX19 | c.777G>A p.E259= | Silent (SNP) | VAF 98/529 reads (19%) | catalogued as COSV57400077; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1767C>T p.P589= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs370418088; called by muse, mutect2, varscan2
- TENT5C | c.837G>T p.P279= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV65616758; called by muse, mutect2, varscan2
- TKFC | c.1536A>G p.P512= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV53652992; called by muse, mutect2
- TMCO4 | c.411C>T p.L137= | Silent (SNP) | VAF 47/177 reads (27%) | catalogued as rs759854072, COSV53875211; called by muse, mutect2, varscan2
- TTC23L | c.978T>C p.S326= | Silent (SNP) | VAF 79/429 reads (18%) | catalogued as COSV72205991; called by muse, mutect2, varscan2
- TTN | c.17013A>G p.T5671= (on ENST00000591111; = p.T4744= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/301 reads (13%) | catalogued as COSV60213682; called by muse, mutect2
- ZNF93 | c.1530A>G p.K510= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1267040467; called by muse, varscan2
- ALMS1P1 | chr2:73701204 C>T | 3'Flank (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- SLC48A1 | c.*593G>C | 3'UTR (SNP) | VAF 32/129 reads (25%) | catalogued as rs1008874628, COSV50399556, COSV99317018; called by muse, mutect2, varscan2
